Somatic mutation profile of tumor specimen TCGA-DX-A8BO-01A (aliquot TCGA-DX-A8BO-01A-11D-A417-09) from TCGA case TCGA-DX-A8BO, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 67.1 years (24,513 days).
Specimen TCGA-DX-A8BO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 728ddf6f-2913-4f12-8a1c-6d60ea44252f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A8BO-10B (Blood Derived Normal), aliquot TCGA-DX-A8BO-10B-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd5c13d9-3e23-4717-8733-5b63eddd0944

The open-access MAF lists 31 somatic variants for this specimen: 22 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 16, Silent 9, Splice Site 2, Nonsense Mutation 2, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANO7 | c.2497C>T p.R833W (on ENST00000274979; = p.R779W on NM_001370694.2) | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372507979; called by muse, mutect2, varscan2
- BCL7A | c.464A>C p.Q155P | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.454); catalogued as COSV55848157; called by mutect2, varscan2
- DMD | c.2335G>T p.D779Y | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100819032; called by muse, mutect2, varscan2
- GPR37 | c.921C>G p.D307E | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100390705; called by muse, mutect2, varscan2
- IGHV4-34 | c.296C>T p.T99M | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.242); catalogued as rs200873048; called by muse, mutect2, varscan2
- IQGAP3 | c.2563C>T p.R855C | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs751001051, COSV63251278; called by muse, mutect2, varscan2
- KIF1B | c.271G>T p.V91F | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99822959; called by muse, mutect2, varscan2
- KLC2 | c.1236G>A p.W412* | Nonsense Mutation (SNP) | VAF 13/30 reads (43%) | catalogued as COSV100270639; called by muse, mutect2, varscan2
- NR0B1 | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs183613764, CD066384, COSV100973489; called by muse, mutect2, varscan2
- PARP8 | c.2440G>A p.V814I | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.956); catalogued as COSV99890700; called by muse, mutect2, varscan2
- PCSK5 | c.998T>C p.I333T | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100949773; called by muse, mutect2, varscan2
- PXDNL | c.3885G>A p.W1295* | Nonsense Mutation (SNP) | VAF 6/27 reads (22%) | catalogued as COSV100682869; called by muse, mutect2, varscan2
- RB1 | c.939+1G>A p.X313_splice | Splice Site (SNP) | VAF 26/85 reads (31%) | catalogued as COSV57302173, COSV57303447; called by muse, mutect2, varscan2
- RYR2 | c.5827C>G p.R1943G | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100769245; called by muse, mutect2, varscan2
- TOP1MT | c.1470G>C p.K490N | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV100239324; called by muse, mutect2, varscan2
- USP45 | c.1359A>T p.E453D | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV100569572; called by muse, mutect2, varscan2
- WDR24 | c.1595C>T p.T532M (on ENST00000248142; = p.T402M on NM_032259.4) | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs775417149, COSV99555559; called by muse, mutect2, varscan2
- ZNF474 | c.436G>C p.G146R | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV56945770, COSV99682083; called by muse, mutect2
- ADAMTS6 | c.2573G>C p.G858A | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by muse, mutect2
- BCL7A | c.468_489del p.S157Afs*5 | Frame Shift Del (DEL) | VAF 7/39 reads (18%) | called by mutect2, pindel, varscan2
- NR1D2 | c.1432_1458del p.G478_M486del | In Frame Del (DEL) | VAF 17/89 reads (19%) | called by mutect2, pindel, varscan2
- PRAMEF15 | c.876-2A>G p.X292_splice | Splice Site (SNP) | VAF 42/158 reads (27%) | called by muse, mutect2, varscan2
- DCLK3 | c.1683C>T p.D561= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as rs370718609; called by muse, mutect2, varscan2
- FAM135B | c.2022G>A p.G674= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV99421767; called by muse, mutect2, varscan2
- FAM161A | c.1368A>G p.P456= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs1558483269, COSV100281211; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GJD2 | c.273T>C p.L91= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV99290654; called by muse, mutect2, varscan2
- IGFBP7 | c.495C>T p.P165= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as rs1193796118, COSV99825352; called by muse, mutect2, varscan2
- MEOX2 | c.75C>A p.S25= | Silent (SNP) | VAF 3/32 reads (9%) | catalogued as COSV100012085; called by muse, mutect2
- SHBG | c.501C>T p.I167= | Silent (SNP) | VAF 22/37 reads (59%) | catalogued as COSV99352167; called by muse, mutect2, varscan2
- SLC25A32 | c.321G>A p.K107= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV99884345; called by muse, mutect2, varscan2
- ZDHHC1 | c.750C>T p.L250= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs765965981, COSV100799388; called by muse, mutect2, varscan2
